Gene-level copy-number profile of tumor specimen TCGA-BR-8683-01A from TCGA case TCGA-BR-8683, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 75.4 years (27,549 days).
Specimen TCGA-BR-8683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.68cecafe-4e0b-47f7-98d1-0a9ca0732d4e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8683-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff179241-c498-4045-b015-5726329b9465

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 2,257; copy number 2: 2,626; copy number 3: 17,725; copy number 4: 28,595; copy number 5: 4,785; copy number 6: 2,147; copy number 7: 292; copy number 8: 987; copy number 9: 17; copy number 10: 75; copy number 11: 52; copy number 17: 115; copy number 19: 21; copy number 25: 10; copy number 43: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8683-01A-11D-2390-01): tumor purity 0.58, ploidy 4.78, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,959,267–56,191,262, 62 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 339 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:15,102,946–15,663,058, 10 genes, copy number 25 (within-gene range 14–25): AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1.
- chr6:39,934,595–40,000,527, 1 gene, copy number 17 (within-gene range 5–17): TUBBP9.
- chr6:40,271,566–44,450,425, 154 genes, copy number 17–43 (within-gene range 6–43) (broad region; genes not listed).
- chr6:44,809,317–50,913,256, 82 genes, copy number 11–43 (within-gene range 6–43) (broad region; genes not listed).
- chr7:52,165,235–53,863,339, 17 genes, copy number 9: AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3.
- chr20:21,114,723–23,711,406, 75 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,257. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
